MMRF case MMRF_1304 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ae58bf4d-78b2-4e5b-8e58-30a64a519e72

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.0 years (26,307 days); ISS stage: III; Days to last known disease status: 1,542 days (4.2 years); Days to last follow up: 1,542 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 401 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 429 days (1.2 years); Days to treatment end: 1,038 days (2.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,038 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.58 mg/dL; Immunoglobulin G 26.1 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 3.7 g/L; Beta 2 Microglobulin 7.58 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.95 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 7.5 g/dL; Glucose 7.15 mmol/L; C-Reactive Protein 1.73 mg/dL.
- Day 60 (ECOG 1): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 8.27 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 4.24 µg/mL; Lactate Dehydrogenase 1.27 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 156 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 8.07 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 3.25 µg/mL; Lactate Dehydrogenase 1.47 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.03 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 240 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 7.65 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 2.96 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 7.04 mmol/L.
- Day 375 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 3.39 µg/mL; Lactate Dehydrogenase 1.52 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.84 mmol/L.
- Day 458: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 6.6 mmol/L.
- Day 513 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 1.37 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 631: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Lactate Dehydrogenase 1.4 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.41 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 6.44 mmol/L.
- Day 659: Hemoglobin 6.01 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.41 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 161 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 8.09 mmol/L.
- Day 835: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.4 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.54 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 8.42 mmol/L.
- Day 878 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.72 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 3.22 µg/mL; Lactate Dehydrogenase 1.6 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 948: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 9.72 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 175 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.28 mmol/L.
- Day 1,121: M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.44 mg/dL; Lactate Dehydrogenase 1.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.72 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.78 mmol/L.
- Day 1,262: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 3.04 µg/mL; Lactate Dehydrogenase 1.6 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 1,375: M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Lactate Dehydrogenase 1.35 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 8.53 mmol/L.
- Day 1,459: M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Lactate Dehydrogenase 1.53 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.69 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 1,542: Hemoglobin 7.69 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.24 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day -5: Weight: 85 kg; Height: 179 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1304_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1304_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
